Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5EY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5EY-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					male	caucasian	Astrocytoma		Brain, right hemisphere, lobe	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Diffuse astrocytoma	2	n/a	n/a	n/a	none	n/a	80
					male	caucasian	Astrocytoma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3
Astrocytoma, diffuse G40013
Site: (R) Brain, Supratentorial C71.0
JED 4/2/13

Criteria	W 12/19/12	Yes	No
Transports Discrepancy			☒
RT AA Discrepancy			☒
Prior Primary History			☒
Concurrent Primary History			☒

Source: NCI Genomic Data Commons file 89950e61-77dd-4ba9-b4b5-d3665d5766d6 (TCGA-P5-A5EY.13BDC5C7-92EB-4FCD-ACAB-8005C2F099D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).